Somatic mutation profile of tumor specimen ASCProject_0005_T3_WES (aliquot ASCProject_0005_T3_WES_1) from CMI case ASCProject_0005, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 31.1 years (11,349 days).
Specimen ASCProject_0005_T3_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Back; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5c833ec-8ac0-451b-abc3-2ae70f209408.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0005_SALIVA (Saliva), aliquot ASCProject_0005_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/737434e0-4ee4-4847-a634-6bbf23ae7e29

The open-access MAF lists 37 somatic variants for this specimen: 20 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 11, Splice Region 2, Intron 2, 3'UTR 2, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL24A1 | c.3570G>A p.K1190= | Splice Region (SNP) | VAF 49/236 reads (21%) | catalogued as COSV65306250; called by muse, mutect2, varscan2
- COL6A5 | c.1378C>A p.Q460K | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.338); catalogued as rs1207893002, COSV55211853; called by muse, mutect2, varscan2
- EMSY | c.893A>G p.H298R | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.253); catalogued as rs772695634; called by muse, mutect2, varscan2
- NRXN3 | c.1400G>A p.R467H (on ENST00000335750 / NM_001330195.2; = p.R94H on NM_004796.6) | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs746783604; called by muse, mutect2, varscan2
- PIK3CA | c.320A>C p.N107T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55918383, COSV55932743, COSV55991103; called by muse, mutect2
- PLCG1 | c.3493G>C p.D1165H | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54814749; called by muse, mutect2, varscan2
- POT1 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 132/375 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780936436, CM1510290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SI | c.4757G>C p.R1586T | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52280805; called by muse, mutect2, varscan2
- SPZ1 | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV57063263, COSV99698308; called by mutect2, varscan2
- TP53BP1 | c.5437C>G p.R1813G | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53017916; called by muse, mutect2, varscan2
- CAP1 | c.782T>G p.I261S | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2
- CBR3 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD1B | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRH | c.38T>G p.L13R | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- H2AC17 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYCBP2 | c.10424C>T p.S3475F (on ENST00000357337; = p.S3513F on NM_015057.5) | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MYH16 | n.4498G>T | Splice Region (SNP) | VAF 40/106 reads (38%) | called by mutect2, varscan2
- QKI | c.721dup p.L241Pfs*49 | Frame Shift Ins (INS) | VAF 54/264 reads (20%) | called by mutect2, pindel, varscan2
- UGT2A3 | c.506C>A p.T169K | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- WDR19 | c.1891T>C p.Y631H | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AL592490.1 | c.1098A>T p.A366= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- BIN2 | c.285T>G p.G95= | Silent (SNP) | VAF 48/215 reads (22%) | called by muse, mutect2
- CACNA2D2 | c.1569C>T p.G523= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as rs763047983, COSV99817978; called by muse, mutect2, varscan2
- ENPP3 | c.2526A>G p.V842= | Silent (SNP) | VAF 65/356 reads (18%) | called by muse, mutect2, varscan2
- FMN2 | c.2496T>C p.S832= | Silent (SNP) | VAF 67/235 reads (29%) | called by muse, mutect2, varscan2
- MYH8 | c.1020C>T p.D340= | Silent (SNP) | VAF 66/293 reads (23%) | called by muse, mutect2, varscan2
- NAA25 | c.582T>A p.A194= | Silent (SNP) | VAF 21/85 reads (25%) | called by muse, varscan2
- SCML2 | c.1956C>T p.A652= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV99319081; called by muse, mutect2, varscan2
- UBB | c.564C>T p.I188= | Silent (SNP) | VAF 138/604 reads (23%) | catalogued as rs774034549; called by mutect2, varscan2
- VGLL3 | c.600C>A p.P200= | Silent (SNP) | VAF 63/320 reads (20%) | called by muse, mutect2, varscan2
- ZRANB3 | c.1173C>T p.R391= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as rs776799423, COSV51517854; called by muse, mutect2, varscan2
- CTTN | c.*545A>C | 3'UTR (SNP) | VAF 100/364 reads (27%) | called by muse, mutect2, varscan2
- FLT4 | c.3332-32G>A | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2
- FOXI2 | chr10:127736628 G>T | 5'Flank (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.39G>T | RNA (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- MYPN | c.*1038A>G | 3'UTR (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- TRNT1 | c.148+791A>C | Intron (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
